Somatic mutation profile of tumor specimen MMRF_2732_1_BM_CD138pos (aliquot MMRF_2732_1_BM_CD138pos_T1_KHS5U_L14876) from MMRF case MMRF_2732, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.5 years (20,648 days).
Specimen MMRF_2732_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5be6657-d6a8-4cb3-ac8d-1f8d9807d56f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2732_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2732_1_PB_WBC_C3_KHS5U_L14878; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed395a37-5a24-4c06-801a-6895c66f39f5

The open-access MAF lists 151 somatic variants for this specimen: 62 protein-altering or splice-affecting, 16 silent, 73 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, 3'UTR 36, Intron 21, Silent 16, 5'UTR 5, RNA 4, 3'Flank 4, 5'Flank 3, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC093246.1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as rs984975545, COSV51125252; called by muse, mutect2
- ACADL | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52052825; called by muse, mutect2, varscan2
- ADAMTS20 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 122/239 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1216030314, COSV101239668; called by muse, mutect2, varscan2
- ADGRB3 | c.2398G>A p.D800N | Missense Mutation (SNP) | VAF 156/348 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.27); catalogued as rs754848273, COSV65395147, COSV65421513; called by muse, mutect2, varscan2
- C4orf54 | c.2651C>T p.A884V | Missense Mutation (SNP) | VAF 84/88 reads (95%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.871); catalogued as COSV72766907; called by muse, mutect2, varscan2
- COL18A1 | c.1696G>A p.A566T (on ENST00000359759 / NM_130444.3; = p.A331T on NM_030582.4) | Missense Mutation (SNP) | VAF 101/214 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201833726; called by muse, mutect2, varscan2
- FAM135B | c.4087C>T p.R1363* | Nonsense Mutation (SNP) | VAF 10/162 reads (6%) | catalogued as rs758974242, COSV52734447; called by muse, mutect2
- GRM8 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201540505; called by muse, mutect2, varscan2
- H1-4 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV104388570; called by muse, mutect2, varscan2
- IPPK | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV55334759, COSV55335782; called by muse, mutect2, varscan2
- LMBR1L | c.475A>G p.M159V | Missense Mutation (SNP) | VAF 74/147 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1167324299; called by muse, mutect2, varscan2
- LRRC14B | c.1174C>A p.Q392K | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV57256585; called by muse, mutect2, varscan2
- MUC16 | c.23131C>A p.P7711T | Missense Mutation (SNP) | VAF 108/317 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.266); catalogued as rs578258727, COSV67455199; called by muse, mutect2, varscan2
- MYH1 | c.1483C>T p.H495Y | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs777299446; called by muse, mutect2, varscan2
- NEB | c.7576G>A p.G2526S | Missense Mutation (SNP) | VAF 220/466 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs745615339; called by muse, mutect2, varscan2
- OOEP | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 111/240 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs879665795, COSV64859098; called by muse, mutect2, varscan2
- OR1C1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 242/509 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV68715803; called by muse, mutect2, varscan2
- RIBC1 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 95/97 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1556894251, COSV51448891; called by muse, mutect2, varscan2
- ROBO2 | c.3361G>C p.E1121Q | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as COSV100166803; called by muse, mutect2, varscan2
- RUNX1 | c.401T>C p.L134P (on ENST00000344691 / NM_001001890.3; = p.L161P on NM_001754.5) | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55869984; called by muse, mutect2, varscan2
- SERPINA4 | c.883C>G p.P295A | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV100096984; called by muse, mutect2
- SMOC2 | c.1214C>T p.S405F (on ENST00000356284 / NM_001166412.2; = p.S416F on NM_022138.3) | Missense Mutation (SNP) | VAF 80/96 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV62436745; called by muse, mutect2, varscan2
- TBC1D16 | c.905A>G p.D302G | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60477690; called by muse, mutect2
- TCF4 | c.929G>A p.R310K | Missense Mutation (SNP) | VAF 93/193 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs1166273670; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3161G>C p.G1054A | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.192); catalogued as COSV51959829; called by muse, mutect2, varscan2
- ZNF583 | c.1558T>C p.Y520H | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV52401793; called by muse, mutect2
- ZNF883 | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778907883; called by muse, mutect2, varscan2
- CIT | c.5542G>A p.E1848K | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- CNTNAP5 | c.1346T>G p.L449R | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.025); called by muse, mutect2
- DIS3L2 | c.1709G>A p.C570Y | Missense Mutation (SNP) | VAF 182/378 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DNAH11 | c.4952G>A p.C1651Y | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2
- ELK4 | c.949T>A p.S317T | Missense Mutation (SNP) | VAF 64/280 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- EML6 | c.4309A>T p.I1437L | Missense Mutation (SNP) | VAF 79/144 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAM178B | c.764T>C p.L255P | Missense Mutation (SNP) | VAF 117/233 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FAM47B | c.1720C>G p.L574V | Missense Mutation (SNP) | VAF 110/115 reads (96%) | SIFT tolerated (0.12); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- FBN2 | c.4217G>T p.C1406F | Missense Mutation (SNP) | VAF 179/373 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HNRNPUL2 | c.1394A>T p.K465M | Missense Mutation (SNP) | VAF 106/234 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IPO11 | c.2807T>A p.F936Y | Missense Mutation (SNP) | VAF 175/402 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.014); called by muse, varscan2
- JAML | c.1061G>A p.S354N (on ENST00000356289 / NM_001098526.2; = p.S344N on NM_153206.3) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KDM1B | c.1548C>G p.I516M | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LRRC14B | c.1175A>G p.Q392R | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAP1B | c.6790A>C p.K2264Q | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2
- MUC19 | c.634_637delinsGGA p.E212Gfs*64 | Frame Shift Del (DEL) | VAF 53/218 reads (24%) | called by pindel, varscan2*
- OBSL1 | c.2207T>G p.L736R | Missense Mutation (SNP) | VAF 112/263 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- PHACTR2 | c.385dup p.T129Nfs*11 | Frame Shift Ins (INS) | VAF 67/96 reads (70%) | called by mutect2, pindel, varscan2
- PHLPP2 | c.773G>A p.C258Y | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLEKHA4 | c.1430G>A p.R477K | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.952); called by muse, mutect2
- PTPRD | c.3380A>G p.Q1127R | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBBP7 | c.162-1G>A p.X54_splice | Splice Site (SNP) | VAF 28/87 reads (32%) | called by muse, mutect2, varscan2
- RBBP7 | c.17-5T>G | Splice Region (SNP) | VAF 33/117 reads (28%) | called by muse, mutect2, varscan2
- ROBO1 | c.3056A>T p.Y1019F | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- RPP30 | c.195G>T p.Q65H | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SGCE | c.1010A>G p.Y337C (on ENST00000647096; = p.Y301C on NM_003919.3) | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM40 | c.666G>C p.Q222H | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TNC | c.1654G>T p.G552* | Nonsense Mutation (SNP) | VAF 125/279 reads (45%) | called by muse, mutect2, varscan2
- TOPORS | c.2266C>T p.H756Y | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRAF3 | c.1393A>G p.M465V | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.526); called by muse, mutect2
- TRPM4 | c.3509A>C p.Q1170P | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- XRN1 | c.173A>C p.D58A | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- ZNF292 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF567 | c.1175C>A p.P392H (on ENST00000536254 / NM_001322913.1; = p.P361H on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 114/237 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF770 | c.17A>T p.N6I | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.038); called by muse, mutect2
- AGGF1 | c.222C>T p.L74= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs769141163; called by muse, mutect2, varscan2
- AGRN | c.3300C>T p.V1100= | Silent (SNP) | VAF 67/72 reads (93%) | catalogued as rs935964266; ClinVar: likely benign; called by muse, mutect2, varscan2
- BMS1 | c.3663G>A p.K1221= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as rs150743357; called by muse, mutect2, varscan2
- CACNA1D | c.5547G>A p.E1849= (on ENST00000350061 / NM_001128840.3; = p.E1869= on NM_000720.4) | Silent (SNP) | VAF 20/85 reads (24%) | called by muse, mutect2, varscan2
- CFAP221 | c.1689A>C p.S563= | Silent (SNP) | VAF 81/209 reads (39%) | called by muse, mutect2, varscan2
- DYSF | c.3570G>T p.V1190= | Silent (SNP) | VAF 100/207 reads (48%) | called by muse, mutect2, varscan2
- ELOVL3 | c.741C>T p.F247= | Silent (SNP) | VAF 31/155 reads (20%) | catalogued as rs1320039036; called by muse, mutect2, varscan2
- INSR | c.3744T>C p.F1248= | Silent (SNP) | VAF 56/173 reads (32%) | called by muse, mutect2, varscan2
- LRRC34 | c.1086C>T p.N362= (on ENST00000446859 / NM_001172779.2; = p.N330= on NM_153353.5) | Silent (SNP) | VAF 7/167 reads (4%) | called by muse, mutect2
- MAGEC3 | c.930G>C p.G310= | Silent (SNP) | VAF 65/70 reads (93%) | called by muse, mutect2
- NOTCH3 | c.882G>A p.T294= | Silent (SNP) | VAF 127/384 reads (33%) | catalogued as rs998446906, COSV54625929; called by muse, mutect2, varscan2
- OR10P1 | c.45G>A p.L15= | Silent (SNP) | VAF 66/350 reads (19%) | catalogued as rs1430371866; called by muse, mutect2, varscan2
- PCDHB8 | c.885C>T p.V295= | Silent (SNP) | VAF 107/471 reads (23%) | catalogued as COSV50792817; called by muse, mutect2, varscan2
- PKNOX2 | c.369C>T p.F123= | Silent (SNP) | VAF 39/210 reads (19%) | catalogued as COSV100021019; called by muse, mutect2, varscan2
- PREX1 | c.3582C>T p.G1194= | Silent (SNP) | VAF 113/268 reads (42%) | catalogued as COSV64252618; called by muse, mutect2, varscan2
- TEX13C | c.813A>G p.P271= | Silent (SNP) | VAF 132/136 reads (97%) | called by muse, mutect2, varscan2
- AC093536.1 | n.33C>T | RNA (SNP) | VAF 67/164 reads (41%) | called by muse, mutect2, varscan2
- ADORA1 | c.*1278G>T | 3'UTR (SNP) | VAF 20/87 reads (23%) | catalogued as rs1266556813; called by muse, mutect2, varscan2
- AGBL1 | c.970-16G>A | Intron (SNP) | VAF 90/196 reads (46%) | called by muse, mutect2
- AP003548.1 | n.114C>A | RNA (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2
- AP2A2 | c.-58G>A | 5'UTR (SNP) | VAF 3/41 reads (7%) | catalogued as rs1415609119; called by muse, mutect2
- ARNT | c.*1669T>A | 3'UTR (SNP) | VAF 10/193 reads (5%) | called by muse, mutect2
- ATP8B3 | c.751-65G>A | Intron (SNP) | VAF 80/235 reads (34%) | called by muse, mutect2, varscan2
- BRWD1 | c.6571+3377G>A | Intron (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- C4orf36 | c.*59C>T | 3'UTR (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- C9orf64 | c.597+1712dup | Intron (INS) | VAF 20/58 reads (34%) | called by mutect2, varscan2
- CACNA2D1 | chr7:81948713 del AAAG | 3'Flank (DEL) | VAF 12/61 reads (20%) | called by mutect2, pindel, varscan2
- CBFA2T2 | c.*1668del | 3'UTR (DEL) | VAF 37/93 reads (40%) | called by mutect2, pindel, varscan2
- CUL2 | c.*327C>T | 3'UTR (SNP) | VAF 13/27 reads (48%) | catalogued as rs15460; called by muse, mutect2, varscan2
- CXCL12 | c.*2142T>C | 3'UTR (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- DAB2IP | c.*169G>A | 3'UTR (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- DIDO1 | c.3541+2690G>A | Intron (SNP) | VAF 216/431 reads (50%) | catalogued as rs574925653; called by muse, mutect2, varscan2
- EBF2 | c.-491A>C | 5'UTR (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- ERLIN2 | c.*4141C>A | 3'UTR (SNP) | VAF 43/68 reads (63%) | called by muse, mutect2, varscan2
- ESR1 | c.*4035_*4038del | 3'UTR (DEL) | VAF 41/49 reads (84%) | called by mutect2, pindel, varscan2
- EVX2 | c.-108A>C | 5'UTR (SNP) | VAF 61/137 reads (45%) | called by muse, mutect2, varscan2
- FAF2 | chr5:176447847 G>T | 5'Flank (SNP) | VAF 166/390 reads (43%) | called by muse, mutect2, varscan2
- FAM229A | c.282-22del | Intron (DEL) | VAF 40/57 reads (70%) | called by mutect2, pindel, varscan2
- FRG2C | c.*339_*341del | 3'UTR (DEL) | VAF 48/126 reads (38%) | called by pindel, varscan2
- GFRA2 | chr8:21691922 C>T | 3'Flank (SNP) | VAF 91/176 reads (52%) | called by muse, mutect2, varscan2
- GRB2 | c.*1537T>C | 3'UTR (SNP) | VAF 113/269 reads (42%) | catalogued as rs960656505; called by muse, mutect2, varscan2
- GSK3B | c.*102dup | 3'UTR (INS) | VAF 110/258 reads (43%) | catalogued as rs746458626; called by mutect2, varscan2
- HHLA2 | c.1225-185A>C | Intron (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- HINFP | c.-10-896A>C | Intron (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2, varscan2
- HLA-G | chr6:29827674 C>T | 5'Flank (SNP) | VAF 12/94 reads (13%) | catalogued as rs1026619712; called by muse, mutect2
- JDP2 | chr14:75472125 T>G | 3'Flank (SNP) | VAF 49/59 reads (83%) | called by muse, mutect2, varscan2
- KCNK3 | c.*4538C>T | 3'UTR (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- KCTD20 | c.*605A>G | 3'UTR (SNP) | VAF 31/73 reads (42%) | catalogued as rs749839463; called by muse, mutect2, varscan2
- KDM4A | c.*661C>T | 3'UTR (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- MBLAC2 | c.-247_-223del | 5'UTR (DEL) | VAF 46/118 reads (39%) | called by mutect2, pindel, varscan2
- MLLT6 | c.*1405C>T | 3'UTR (SNP) | VAF 6/60 reads (10%) | catalogued as rs896509669; called by muse, mutect2, varscan2
- MS4A4A | c.*737T>C | 3'UTR (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- MYH11 | c.2058+63C>A | Intron (SNP) | VAF 80/164 reads (49%) | called by muse, mutect2, varscan2
- NUDT22 | c.678-39G>A | Intron (SNP) | VAF 88/187 reads (47%) | called by muse, mutect2, varscan2
- P2RX1 | c.137+519C>T | Intron (SNP) | VAF 88/160 reads (55%) | called by muse, mutect2, varscan2
- PCDH17 | c.*3553A>G | 3'UTR (SNP) | VAF 46/122 reads (38%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2388+4811C>T | Intron (SNP) | VAF 40/96 reads (42%) | catalogued as COSV100248800; called by muse, mutect2, varscan2
- PPP1R12B | c.*4256C>T | 3'UTR (SNP) | VAF 23/260 reads (9%) | called by muse, mutect2
- PRKAR2A | c.*975T>C | 3'UTR (SNP) | VAF 46/94 reads (49%) | called by muse, mutect2, varscan2
- PSMC5 | c.265-45G>A | Intron (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- RAP1GAP | c.-149+3959G>A | Intron (SNP) | VAF 145/151 reads (96%) | catalogued as rs771650388; called by muse, mutect2, varscan2
- RBBP8 | c.-274G>A | 5'UTR (SNP) | VAF 38/64 reads (59%) | called by muse, mutect2, varscan2
- RGS16 | c.*359A>C | 3'UTR (SNP) | VAF 23/511 reads (5%) | called by muse, mutect2
- RHPN2P1 | n.1363A>T | RNA (SNP) | VAF 44/286 reads (15%) | called by muse, mutect2, varscan2
- RN7SL860P | chr19:22602002 G>A | 3'Flank (SNP) | VAF 8/199 reads (4%) | catalogued as rs1437860524; called by muse, mutect2
- RPL28 | c.206-176G>C | Intron (SNP) | VAF 23/36 reads (64%) | called by muse, mutect2, varscan2
- RRP1B | c.*1377G>A | 3'UTR (SNP) | VAF 109/230 reads (47%) | called by muse, mutect2, varscan2
- RTF2 | c.69+1944G>A | Intron (SNP) | VAF 79/162 reads (49%) | called by muse, mutect2, varscan2
- SCIN | chr7:12570719 C>T | 5'Flank (SNP) | VAF 38/258 reads (15%) | called by muse, varscan2
- SETD2 | c.*46C>G | 3'UTR (SNP) | VAF 73/129 reads (57%) | called by muse, mutect2, varscan2
- SLC35B4 | c.673+70_673+74del | Intron (DEL) | VAF 32/274 reads (12%) | called by pindel, varscan2
- SLIT3 | c.*3991A>T | 3'UTR (SNP) | VAF 82/198 reads (41%) | called by muse, mutect2
- SLIT3 | c.*3085C>T | 3'UTR (SNP) | VAF 75/139 reads (54%) | called by muse, mutect2, varscan2
- SMPD4 | c.*245G>A | 3'UTR (SNP) | VAF 37/81 reads (46%) | catalogued as rs1332727034; called by muse, mutect2, varscan2
- SPEN | c.404+887C>T | Intron (SNP) | VAF 4/31 reads (13%) | catalogued as rs1319889067; called by muse, mutect2, varscan2
- SUPT5H | c.624+41A>C | Intron (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- SYCE1 | c.*142C>A | 3'UTR (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- TNRC18P2 | n.1147C>A | RNA (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- TPM1 | c.241-82A>C | Intron (SNP) | VAF 43/118 reads (36%) | called by muse, mutect2, varscan2
- TRDN | c.484+1291G>T | Intron (SNP) | VAF 187/199 reads (94%) | catalogued as rs1016125941, COSV62136307; called by muse, mutect2, varscan2
- TRIM14 | c.*2791_*2795del | 3'UTR (DEL) | VAF 10/62 reads (16%) | called by pindel, varscan2
- UBA6 | c.*2401G>A | 3'UTR (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- VGLL3 | c.*5217G>T | 3'UTR (SNP) | VAF 22/60 reads (37%) | called by muse, varscan2
- ZNF445 | c.*1650G>A | 3'UTR (SNP) | VAF 46/98 reads (47%) | called by muse, mutect2, varscan2
- ZNF600 | c.*100A>T | 3'UTR (SNP) | VAF 104/246 reads (42%) | called by muse, mutect2, varscan2
- ZNF7 | c.*92A>C | 3'UTR (SNP) | VAF 100/228 reads (44%) | called by muse, mutect2, varscan2
- ZNF721 | c.*1284T>A | 3'UTR (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2, varscan2
- ZNF772 | c.*1948dup | 3'UTR (INS) | VAF 22/57 reads (39%) | catalogued as rs869168370; called by mutect2, varscan2
- ZNF813 | c.*3456dup | 3'UTR (INS) | VAF 31/82 reads (38%) | catalogued as rs1424672844; called by mutect2, varscan2
